CCDI case PBCESA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad8d7b1c-7d0d-4ce0-90b8-96e7c36177e3

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.1 years (1,864 days).

Biospecimens (3 samples)
- Sample 0DQMPO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQMQ3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQMQU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
